Somatic mutation profile of tumor specimen TCGA-D3-A2JK-06A (aliquot TCGA-D3-A2JK-06A-11D-A196-08) from TCGA case TCGA-D3-A2JK, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 25.0 years (9,128 days).
Specimen TCGA-D3-A2JK-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eccc630b-d720-4272-97f3-bf34bf6cd780.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JK-10A (Blood Derived Normal), aliquot TCGA-D3-A2JK-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09c47ed7-f138-428d-8156-31cd11f7fe88

The open-access MAF lists 351 somatic variants for this specimen: 227 protein-altering or splice-affecting, 119 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 119, Nonsense Mutation 15, Splice Region 5, Intron 2, Splice Site 2, RNA 2, Nonstop Mutation 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PTEN | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as rs371387815, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2852C>T p.S951F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV55941412; called by muse, mutect2, varscan2
- ABCB9 | c.1246A>T p.S416C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54894165; called by muse, mutect2, varscan2
- ABCG4 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56645699; called by muse, mutect2, varscan2
- ADAM15 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); catalogued as rs752448335, COSV55063117; called by muse, mutect2
- ADAMTS20 | c.5083C>T p.H1695Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV67130492, COSV67138776; called by muse, mutect2, varscan2
- ADCY10 | c.4192G>A p.E1398K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV63244747; called by muse, mutect2, varscan2
- AFF1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs770012308, COSV57123839; called by muse, mutect2, varscan2
- AGTPBP1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61277180; called by muse, mutect2, varscan2
- AGXT | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56755246; called by muse, mutect2, varscan2
- AHDC1 | c.4664C>T p.S1555L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs781513175, COSV55941531; called by muse, mutect2, varscan2
- AKAP8L | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV101275834; called by muse, mutect2, varscan2
- ALAS2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV58193185; called by muse, mutect2, varscan2
- ALPK3 | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.045); catalogued as rs756635127, COSV51939499; called by mutect2, varscan2
- ANKRD30A | c.2941C>T p.H981Y (on ENST00000611781; = p.H925Y on NM_052997.2) | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs766785249, COSV64613073, COSV64620501; called by muse, mutect2, varscan2
- ANKRD30A | c.3539C>T p.S1180F (on ENST00000611781; = p.S1124F on NM_052997.2) | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV64620510; called by muse, mutect2, varscan2
- ANO1 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs372809100, COSV60289022; called by muse, mutect2, varscan2
- APBB3 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100021411; called by muse, mutect2, varscan2
- APCDD1L | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs761827739, COSV64485444; called by muse, mutect2, varscan2
- ARHGAP21 | c.1790G>A p.R597K | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV57610812; called by muse, mutect2, varscan2
- ARHGAP32 | c.4597C>T p.R1533C (on ENST00000310343 / NM_001378025.1; = p.R1184C on NM_014715.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs142674734; called by muse, mutect2, varscan2
- ARHGAP39 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV99431826; called by muse, mutect2, varscan2
- ARHGEF10 | c.701C>T p.P234L (on ENST00000398564; = p.P209L on NM_014629.4) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV50675932; called by muse, varscan2
- ARL13B | c.486+2T>C p.X162_splice (on ENST00000394222 / NM_001174150.2; = p.X55_splice on NM_144996.4) | Splice Site (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100115646; called by mutect2, varscan2
- ARRDC4 | c.1202T>G p.V401G | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV99164420; called by muse, mutect2, varscan2
- ARRDC4 | c.1203T>G p.V401= | Splice Region (SNP) | VAF 55/183 reads (30%) | catalogued as COSV99164421; called by muse, mutect2, varscan2
- ASXL3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52478934; called by muse, mutect2, varscan2
- ATP5MPL | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as COSV54603759; called by muse, mutect2, varscan2
- B3GALNT1 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV57581161; called by muse, mutect2, varscan2
- B3GAT3 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs149098151, COSV53883054; called by muse, mutect2, varscan2
- BCHE | c.1770C>G p.N590K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.305); catalogued as COSV52259851, COSV52262240; called by muse, mutect2, varscan2
- BDP1 | c.4259C>T p.P1420L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV62434533; called by muse, mutect2, varscan2
- BIN2 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); catalogued as COSV57207910; called by muse, mutect2, varscan2
- BRINP1 | c.2268G>A p.M756I | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56312621; called by muse, mutect2, varscan2
- BSN | c.5723C>T p.P1908L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV99609165; called by muse, mutect2, varscan2
- CATSPER4 | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58794648; called by muse, mutect2, varscan2
- CATSPERB | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV56434840; called by muse, mutect2, varscan2
- CD101 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.231); catalogued as COSV56720936; called by muse, mutect2, varscan2
- CD177 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100946026; called by muse, mutect2, varscan2
- CDH18 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV56913137; called by muse, varscan2
- CELF4 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58465696; called by muse, varscan2
- CGN | c.3611A>T p.*1204Lext*58 | Nonstop Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV54973518; called by muse, mutect2, varscan2
- CHIT1 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 40/122 reads (33%) | catalogued as rs867379480, COSV55149834; called by muse, mutect2, varscan2
- CLSTN3 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV56936453; called by muse, mutect2, varscan2
- COL22A1 | c.4186G>A p.G1396R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57359508; called by muse, mutect2, varscan2
- COL3A1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58589665; called by muse, mutect2, varscan2
- COL5A3 | c.5161G>A p.D1721N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV53418736; called by muse, mutect2, varscan2
- CPEB1 | c.1336C>T p.P446S (on ENST00000617958; = p.P381S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.066); catalogued as COSV55621377; called by muse, varscan2
- CPT1A | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80356791, CM021572, CM118246, COSV55760666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRTC1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58723181; called by muse, mutect2, varscan2
- CRYBB2 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1267948608, COSV68005761; called by mutect2, varscan2
- CSMD3 | c.7988G>A p.R2663Q (on ENST00000297405 / NM_001363185.1; = p.R2559Q on NM_052900.3) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.763); catalogued as rs1457467270, COSV52202931; called by muse, mutect2, varscan2
- DCLK2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56201484; called by muse, mutect2, varscan2
- DDX60 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs774897680, COSV67099209; called by muse, varscan2
- DEPDC5 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as COSV56710301; called by muse, mutect2, varscan2
- DHX33 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV56580839; called by muse, mutect2, varscan2
- DHX35 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as rs758737112, COSV52674294; called by muse, mutect2, varscan2
- DHX58 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.476); catalogued as COSV52428150; called by muse, mutect2, varscan2
- DIDO1 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs759451853, COSV56628466, COSV56632292; called by muse, mutect2, varscan2
- DIP2B | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99998973; called by muse, mutect2, varscan2
- DLGAP4 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV59423162; called by mutect2, varscan2
- DNAAF3 | c.272T>G p.M91R (on ENST00000524407 / NM_001256715.2; = p.M138R on NM_178837.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV66994294; called by muse, mutect2, varscan2
- DNAH11 | c.9019G>A p.A3007T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.299); catalogued as rs375511101, COSV100179902; called by muse, mutect2, varscan2
- DNAH3 | c.3721-1G>A p.X1241_splice | Splice Site (SNP) | VAF 45/146 reads (31%) | catalogued as COSV54528739, COSV54549857; called by muse, mutect2, varscan2
- DNAH5 | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV54230014; called by muse, mutect2, varscan2
- DSCAM | c.4750G>A p.E1584K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs758792903, COSV68021636; called by mutect2, varscan2
- DSG1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs754465552, COSV57135031; called by muse, mutect2, varscan2
- EFHC1 | c.1462A>T p.S488C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV64137769; called by muse, mutect2, varscan2
- EMILIN1 | c.1510G>A p.V504M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs1190925471, COSV53157206; called by muse, mutect2, varscan2
- ENAH | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.982); catalogued as COSV52872545; called by muse, mutect2, varscan2
- ENPP4 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV58090014; called by muse, varscan2
- ERICH3 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.301); catalogued as rs758911412, COSV58617820; called by muse, mutect2, varscan2
- EXD1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV59256437; called by muse, mutect2, varscan2
- EXPH5 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56205120; called by muse, mutect2, varscan2
- EYA1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as rs1389336466, COSV58173650; called by muse, mutect2, varscan2
- FAAP20 | c.314A>T p.H105L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101052042; called by muse, mutect2, varscan2
- FAM47A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV60495968, COSV60498995; called by muse, varscan2
- FARP2 | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.484); catalogued as COSV50871896; called by muse, mutect2, varscan2
- FIGNL1 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765785150, COSV63554060; called by mutect2, varscan2
- FLG | c.5033G>A p.G1678E | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV64240233, COSV64248586; called by muse, mutect2, varscan2
- FLNB | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99914013; called by muse, mutect2, varscan2
- FREM1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV66527818; called by muse, mutect2, varscan2
- FRMD1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV51961546; called by muse, varscan2
- FRMPD2 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.625); catalogued as COSV59723471; called by muse, mutect2, varscan2
- FYTTD1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54082603; called by muse, mutect2, varscan2
- FZD8 | c.1728C>A p.D576E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.18); catalogued as COSV65968470; called by muse, mutect2, varscan2
- FZD8 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.121); catalogued as rs780684132, COSV65968410; called by mutect2, varscan2
- GALNT13 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs750826926, COSV67238283; called by muse, mutect2, varscan2
- GALNT16 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs764032316, COSV61884421; called by muse, mutect2, varscan2
- GCKR | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as rs765148264, COSV53108018; called by muse, mutect2, varscan2
- GCNT1 | c.480T>A p.D160E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1474690487, COSV65058769; called by muse, mutect2, varscan2
- GEM | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52599034; called by muse, mutect2, varscan2
- GKN1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV65006882; called by muse, mutect2, varscan2
- GPC6 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65536765; called by muse, mutect2, varscan2
- GPD1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.096); catalogued as COSV56549123; called by muse, mutect2, varscan2
- GRIN2B | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74205066; called by muse, mutect2, varscan2
- GSDMC | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.168); catalogued as COSV52697500; called by muse, mutect2, varscan2
- GTPBP8 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs549530387, COSV55606160, COSV55607483; called by muse, mutect2, varscan2
- GZF1 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57638175; called by muse, mutect2, varscan2
- H4C11 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.118); catalogued as COSV61827467; called by muse, mutect2, varscan2
- HEATR6 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV51745807; called by muse, mutect2, varscan2
- HSP90AB1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV62333292; called by muse, mutect2, varscan2
- HYDIN | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as rs1284749679, COSV55491079, COSV55498562; called by muse, mutect2, varscan2
- HYDIN | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV55498607; called by muse, mutect2, varscan2
- ICE1 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56831963; called by muse, mutect2, varscan2
- IGLV2-11 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs187815581; called by muse, mutect2, varscan2
- IMPA2 | c.689G>A p.W230* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV52321012, COSV52321398; called by muse, varscan2
- KIAA0232 | c.4046G>C p.R1349T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as COSV100300934; called by muse, mutect2, varscan2
- KIAA1109 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV52678553; called by mutect2, varscan2
- KIR3DL2 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 117/380 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99552230; called by muse, mutect2, varscan2
- LAMB4 | c.2354G>A p.G785E | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV52730538; called by muse, mutect2, varscan2
- LBP | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV54143593; called by muse, mutect2, varscan2
- LGI1 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65057784; called by muse, mutect2, varscan2
- LGMN | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs200318849, COSV58405135; called by muse, mutect2, varscan2
- LMOD3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs771330798, COSV70456703; ClinVar: uncertain significance; called by mutect2, varscan2
- LRRC73 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs371800481, COSV99446642; called by mutect2, varscan2
- LSMEM1 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV57197164; called by muse, varscan2
- MAGEA8 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV54064482; called by muse, mutect2, varscan2
- MAN2A1 | c.1985C>T p.S662L | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs746252123, COSV54846697; called by muse, mutect2, varscan2
- MEI1 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.275); catalogued as COSV55907625; called by muse, mutect2, varscan2
- MEP1B | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52499888; called by muse, mutect2, varscan2
- MMP15 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774025590, COSV54681490; called by muse, mutect2, varscan2
- MORC1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs138435095, COSV51713000; called by muse, mutect2, varscan2
- MOSPD3 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.854); catalogued as COSV56158862; called by muse, mutect2, varscan2
- MROH7 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs759039314, COSV59877406; called by muse, mutect2, varscan2
- MTIF2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV55054069; called by muse, mutect2, varscan2
- MTUS2 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV70922333; called by mutect2, varscan2
- MUC16 | c.36115C>T p.R12039W | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs369910554; called by muse, mutect2, varscan2
- MUC16 | c.25300A>C p.S8434R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV67491836; called by muse, mutect2, varscan2
- MYBPC2 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV63099659; called by muse, mutect2, varscan2
- MYH2 | c.3923C>T p.S1308L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55441574, COSV55447854; called by muse, mutect2, varscan2
- MYO15A | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52765577; called by muse, mutect2, varscan2
- MYO7B | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs267598861, COSV67348191; called by muse, mutect2, varscan2
- NALCN | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as COSV51964021; called by muse, mutect2, varscan2
- NANOS2 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100379541; called by muse, mutect2, varscan2
- NDST3 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV56628906; called by muse, mutect2, varscan2
- NELL1 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54310103, COSV54322814; called by muse, mutect2, varscan2
- NID2 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1286155277, COSV53496891, COSV53504093; called by muse, mutect2, varscan2
- NLRP12 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs751219722, COSV60747888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV54760101; called by muse, mutect2, varscan2
- NOBOX | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV56197623; called by muse, mutect2, varscan2
- NOVA1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57487185; called by muse, mutect2, varscan2
- NPAP1 | c.455G>A p.W152* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs773732497, COSV61510853; called by muse, mutect2, varscan2
- NUTM1 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV59218940; called by muse, mutect2, varscan2
- OR11L1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV63315688; called by muse, mutect2, varscan2
- OR1L3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.619); catalogued as rs866315429, COSV59169214; called by muse, mutect2, varscan2
- OR2C1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV59241299; called by muse, mutect2, varscan2
- OR52D1 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776107043, COSV59488290; called by muse, mutect2, varscan2
- OR5P2 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61490183; called by muse, mutect2, varscan2
- OR5T1 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.262); catalogued as COSV100478754, COSV57304723; called by muse, varscan2
- OR6F1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57469387; called by muse, mutect2, varscan2
- PBRM1 | c.3808A>C p.K1270Q (on ENST00000296302 / NM_001366071.2; = p.K1245Q on NM_018313.5) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56260706, COSV56303128; called by muse, mutect2, varscan2
- PEX11B | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs781922976, COSV65197123; called by muse, mutect2, varscan2
- PFDN4 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.202); catalogued as COSV65062902, COSV65063674; called by muse, mutect2, varscan2
- PHLPP1 | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53037906; called by muse, mutect2, varscan2
- PIGQ | c.1489T>G p.Y497D | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV50321004; called by muse, varscan2
- PITPNM2 | c.3029C>T p.A1010V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as rs545525327, COSV54908525; called by muse, mutect2, varscan2
- PKD1 | c.12142G>A p.V4048M (on ENST00000262304 / NM_001009944.3; = p.V4047M on NM_000296.4) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs1337808849, COSV51925243; called by mutect2, varscan2
- PLRG1 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs140568729; called by muse, mutect2, varscan2
- PLXNB1 | c.5105C>T p.S1702F | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV56488317; called by muse, mutect2, varscan2
- PPP3R2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV62456796, COSV62457988; called by muse, mutect2, varscan2
- PPP5C | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs775331289, COSV99183554; called by muse, mutect2, varscan2
- PPP5C | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99183559; called by muse, mutect2, varscan2
- PRDM13 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65030187, COSV65030660; called by mutect2, varscan2
- PRPS1 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV65054281, COSV65054685; called by muse, mutect2, varscan2
- PRSS58 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV73488855; called by muse, mutect2, varscan2
- PTGDR | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 40/127 reads (31%) | catalogued as COSV60095051; called by muse, mutect2, varscan2
- PTH1R | c.491G>A p.W164* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | catalogued as COSV57317724; called by muse, mutect2, varscan2
- RALGAPB | c.1478C>T p.T493I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.354); catalogued as COSV53443947; called by muse, mutect2, varscan2
- RASSF8 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV51455277; called by muse, mutect2, varscan2
- RECQL4 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52882690; called by muse, mutect2, varscan2
- REEP1 | c.114G>A p.W38* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51259354; called by muse, mutect2, varscan2
- RIPPLY3 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV61566593; called by muse, mutect2, varscan2
- RP1 | c.5645C>T p.S1882F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV55122031, COSV55126040; called by muse, mutect2, varscan2
- RPL18 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV50032375; called by muse, mutect2, varscan2
- RPL5 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs371559214; called by muse, mutect2, varscan2
- RPL5 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100240435; called by muse, mutect2, varscan2
- RSPH6A | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV55575325, COSV55576061; called by muse, mutect2, varscan2
- SCN8A | c.4450G>A p.E1484K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV61981333, COSV61992615; called by muse, mutect2, varscan2
- SCN9A | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV100313522, COSV57605229; called by mutect2, varscan2
- SERPINF1 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV54617736; called by muse, mutect2, varscan2
- SEZ6L | c.1515G>A p.R505= | Splice Region (SNP) | VAF 9/45 reads (20%) | catalogued as COSV50658303, COSV99961164; called by muse, mutect2, varscan2
- SH3BGR | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV61324494; called by muse, mutect2, varscan2
- SHROOM3 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs762287204, COSV56039077; called by muse, mutect2
- SIRT7 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV58712595; called by muse, mutect2, varscan2
- SLC26A11 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs561639116, COSV58340576; called by muse, varscan2
- SLC38A1 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 38/109 reads (35%) | catalogued as COSV67063559; called by muse, mutect2, varscan2
- SLC38A4 | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56971132; called by muse, mutect2, varscan2
- SLC9C2 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62949295; called by muse, mutect2, varscan2
- SP140 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV59454842; called by muse, mutect2, varscan2
- SPEF2 | c.3460C>A p.L1154M | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV61553403; called by muse, mutect2, varscan2
- SPHK2 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.426); catalogued as COSV55342075; called by muse, mutect2, varscan2
- SPINK9 | c.216G>A p.K72= | Splice Region (SNP) | VAF 24/50 reads (48%) | catalogued as COSV64957965; called by muse, mutect2, varscan2
- SSH1 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV58460226; called by muse, mutect2, varscan2
- STAT3 | c.242A>T p.H81L | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99232990; called by muse, mutect2, varscan2
- STRIP1 | c.1570C>T p.L524F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63930819; called by muse, mutect2, varscan2
- STRIP2 | c.1554C>T p.I518= | Splice Region (SNP) | VAF 12/35 reads (34%) | catalogued as rs533466869, COSV50803610; called by muse, mutect2, varscan2
- STRN | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as COSV55751972; called by muse, mutect2, varscan2
- STXBP4 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467372; called by muse, mutect2, varscan2
- SYDE2 | c.3269G>A p.G1090E | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58325640; called by muse, mutect2, varscan2
- SYNE1 | c.13358C>T p.S4453F (on ENST00000367255 / NM_182961.4; = p.S4382F on NM_033071.3) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55031843, COSV55096017; called by muse, mutect2, varscan2
- TECTA | c.4689G>A p.K1563= | Splice Region (SNP) | VAF 22/50 reads (44%) | catalogued as COSV50800856; called by muse, mutect2, varscan2
- TENM4 | c.4294A>G p.I1432V | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.891); catalogued as COSV53667963; called by muse, mutect2
- TEP1 | c.5741C>T p.S1914F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV52999729; called by muse, mutect2, varscan2
- TEX15 | c.7690C>T p.P2564S (on ENST00000256246; = p.P2947S on NM_001350162.2) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV56353364; called by muse, mutect2, varscan2
- TICRR | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51546736; called by muse, mutect2, varscan2
- TM2D2 | c.287C>T p.S96F (on ENST00000456397 / NM_078473.3; = p.S53F on NM_031940.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV101166186; called by muse, mutect2, varscan2
- TNFRSF11B | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs748875103, COSV52073995, COSV99817064; called by muse, mutect2, varscan2
- TP63 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.835); catalogued as rs34713855; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV50550765; called by muse, mutect2, varscan2
- TRIM42 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs753214955, COSV53883156, COSV53886066; called by mutect2, varscan2
- TTN | c.20522G>A p.S6841N (on ENST00000591111; = p.S5914N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | PolyPhen benign (0.211); catalogued as rs1325004608, COSV60273528, COSV60332996; called by muse, mutect2, varscan2
- UGT1A9 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60851190; called by muse, mutect2, varscan2
- VEGFC | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV54606150; called by muse, mutect2, varscan2
- VN1R5 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as rs1230816682; called by muse, mutect2, varscan2
- XIRP1 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61140929; called by muse, mutect2, varscan2
- ZBTB1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV62439824; called by muse, mutect2, varscan2
- ZC3H12A | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749029255, COSV66104559, COSV99057833; called by muse, mutect2, varscan2
- ZFYVE1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV59613122; called by muse, varscan2
- ZNF415 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs754309535, COSV54704974; called by muse, mutect2, varscan2
- ZNF569 | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV57598990; called by muse, mutect2, varscan2
- ZP2 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.115); catalogued as COSV54813435; called by muse, mutect2, varscan2
- ZSCAN22 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61639596; called by muse, mutect2, varscan2
- ZSCAN5A | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.928); catalogued as rs1274868780, COSV54226796; called by muse, mutect2, varscan2
- NSF | c.1852_1891del p.F618Kfs*75 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel
- TRAV22 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ABCG5 | c.201G>A p.Q67= | Silent (SNP) | VAF 90/332 reads (27%) | catalogued as COSV53213406; called by muse, mutect2, varscan2
- ABLIM1 | c.1476C>T p.L492= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV53315412; called by muse, mutect2, varscan2
- ADAM15 | c.669C>T p.H223= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs200539947, COSV55063113; called by muse, mutect2, varscan2
- ADAMTS18 | c.1068G>A p.L356= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV51422864; called by muse, mutect2, varscan2
- ADAR | c.2121C>T p.S707= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99426379; called by muse, mutect2, varscan2
- ADGRB1 | c.2115C>T p.T705= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV60103265; called by muse, mutect2, varscan2
- ADGRV1 | c.11433T>C p.D3811= | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as COSV67994853; called by muse, mutect2, varscan2
- AGO1 | c.1749C>T p.A583= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs770625415, COSV64596476; called by muse, varscan2
- ALG12 | c.57C>T p.A19= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs763942380, COSV58208408; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ALPK1 | c.3024C>T p.H1008= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99454701; called by mutect2, varscan2
- ANKRD30A | c.1251C>T p.I417= (on ENST00000611781; = p.I361= on NM_052997.2) | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs267602478, COSV64610474; called by muse, mutect2, varscan2
- APBB3 | c.621G>A p.K207= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100021412; called by muse, mutect2, varscan2
- ASAP1 | c.2325C>T p.F775= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs747583877, COSV63054212; called by muse, mutect2, varscan2
- ATF7IP | c.630C>T p.I210= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs947417704, COSV53777286; called by muse, mutect2, varscan2
- ATG4D | c.417C>T p.D139= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV58763644, COSV58763732; called by muse, mutect2, varscan2
- ATP2C2 | c.387G>A p.K129= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV52301139; called by muse, mutect2, varscan2
- BSN | c.5724C>T p.P1908= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1047764119, COSV99609167; called by muse, mutect2, varscan2
- CAD | c.5385C>T p.I1795= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs115849996, COSV53031616; called by muse, mutect2, varscan2
- CASS4 | c.2307G>A p.A769= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs374797932; called by mutect2, varscan2
- CCDC33 | c.2115G>A p.S705= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs747250887, COSV51432420; called by muse, mutect2, varscan2
- CD177 | c.30G>A p.L10= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV100946025; called by muse, mutect2, varscan2
- CDH5 | c.2127C>T p.I709= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1228043930, COSV58519850; called by mutect2, varscan2
- CEP72 | c.1707G>A p.V569= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs777818681, COSV53796914; called by muse, mutect2, varscan2
- CMTM1 | c.351C>T p.L117= (on ENST00000457188 / NM_181269.3; = p.L234= on NM_052999.4) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV51748259; called by muse, mutect2, varscan2
- CNOT3 | c.1593C>T p.A531= | Silent (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2
- CPAMD8 | c.3795C>T p.S1265= (on ENST00000651564; = p.S1218= on NM_015692.5) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV71596276; called by muse, mutect2, varscan2
- CSMD2 | c.9063G>A p.G3021= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV53882229; called by muse, mutect2, varscan2
- DDX60 | c.1659C>T p.I553= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs763840360, COSV67099203; called by muse, varscan2
- DIRAS1 | c.438C>T p.F146= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV60216638; called by muse, mutect2, varscan2
- DNAH3 | c.849G>A p.K283= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV54549875; called by muse, mutect2, varscan2
- DNAH9 | c.3969C>A p.P1323= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV52375707; called by mutect2, varscan2
- DNM3 | c.768G>A p.R256= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs551266524, COSV62466795; called by muse, mutect2, varscan2
- ECEL1 | c.1611G>A p.K537= | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as COSV58814233; called by muse, mutect2, varscan2
- EHMT1 | c.3834C>T p.A1278= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs886063742, COSV66044914; called by muse, mutect2, varscan2
- ELOA2 | c.1158C>T p.Y386= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs765590230, COSV55308232; called by muse, mutect2, varscan2
- ENPEP | c.669A>G p.E223= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs764462249, COSV54457166; called by muse, varscan2
- ERICH3 | c.3984G>A p.K1328= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as rs777972661, COSV100445719, COSV58604226; called by muse, mutect2, varscan2
- FAAP20 | c.315C>T p.H105= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs772593583, COSV101052041; called by mutect2, varscan2
- FAM47A | c.1212C>A p.P404= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV60499677; called by muse, varscan2
- FAT4 | c.9606C>T p.F3202= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs758295187, COSV58707830; called by muse, mutect2, varscan2
- FCGBP | c.5337G>A p.S1779= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs1411385381; called by muse, mutect2, varscan2
- FCGBP | c.1569C>T p.R523= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- FGF3 | c.306G>A p.R102= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV61926872; called by muse, mutect2, varscan2
- FREM2 | c.8928G>A p.V2976= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV54851691, COSV99749362; called by muse, mutect2, varscan2
- GRHL3 | c.1191G>A p.K397= (on ENST00000350501 / NM_198174.3; = p.K402= on NM_021180.3) | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV52569281; called by muse, mutect2, varscan2
- H2BC11 | c.48G>A p.K16= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs1313702403, COSV60362735; called by muse, mutect2, varscan2
- HEATR6 | c.1977C>T p.S659= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV99482478; called by muse, mutect2, varscan2
- HECTD4 | c.8679C>T p.I2893= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV66399602; called by muse, mutect2, varscan2
- HRH1 | c.225C>T p.I75= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs377397952; called by muse, mutect2, varscan2
- HSP90AB1 | c.1173C>T p.S391= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100807158; called by muse, mutect2, varscan2
- IFT57 | c.867C>T p.L289= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV52712153; called by muse, mutect2, varscan2
- IL1R1 | c.984A>T p.I328= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV52108049; called by muse, mutect2, varscan2
- JARID2 | c.2295C>T p.A765= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV59197485; called by muse, mutect2, varscan2
- KHDRBS2 | c.546G>A p.E182= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV55490286; called by muse, mutect2, varscan2
- KIF6 | c.2032C>T p.L678= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV54693615; called by muse, mutect2, varscan2
- KRT71 | c.1287C>T p.I429= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs751192028, COSV57289077; called by mutect2, varscan2
- LPA | c.5193G>A p.K1731= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1443853123, COSV60311499; called by muse, mutect2, varscan2
- LRRC43 | c.1545G>A p.K515= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as COSV60293309; called by muse, mutect2, varscan2
- LSR | c.783C>T p.L261= (on ENST00000361790; = p.L242= on NM_015925.6) | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV61555875; called by muse, mutect2, varscan2
- MFSD2A | c.1026C>T p.F342= (on ENST00000372809 / NM_001136493.3; = p.F329= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV65685633; called by muse, mutect2, varscan2
- MPP2 | c.1630C>T p.L544= (on ENST00000461854 / NM_001278372.2; = p.L520= on NM_005374.5) | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52240084; called by muse, mutect2, varscan2
- MTERF3 | c.765G>A p.V255= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1365793727, COSV54634472; called by muse, mutect2, varscan2
- MUC16 | c.19962C>T p.S6654= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs756842706, COSV67468022; called by muse, mutect2, varscan2
- MUC17 | c.12315C>T p.F4105= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100072684, COSV60282357; called by muse, mutect2, varscan2
- MUC3A | c.75G>A p.T25= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs777828823, COSV100115030; called by muse, mutect2, varscan2
- MYF6 | c.435G>A p.Q145= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV57353245; called by muse, mutect2, varscan2
- MYH15 | c.5106C>T p.S1702= | Silent (SNP) | VAF 65/213 reads (31%) | catalogued as COSV56316949; called by muse, mutect2, varscan2
- MYO5B | c.4446G>A p.R1482= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV53230511; called by muse, mutect2, varscan2
- NDNF | c.615G>A p.L205= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV65634684; called by muse, mutect2, varscan2
- NF2 | c.1275G>C p.L425= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV58530573; called by muse, mutect2, varscan2
- NFIB | c.213G>A p.K71= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV66620481; called by muse, mutect2, varscan2
- NFRKB | c.861C>T p.I287= (on ENST00000446488 / NM_001143835.2; = p.I312= on NM_006165.3) | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV58760375; called by muse, mutect2, varscan2
- NOTCH1 | c.444C>T p.P148= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs904315692, COSV53092453; called by muse, mutect2, varscan2
- OR4D9 | c.753C>T p.F251= | Silent (SNP) | VAF 72/179 reads (40%) | catalogued as rs771977144, COSV61434214; called by muse, mutect2, varscan2
- OR51B4 | c.360C>T p.F120= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV100970557, COSV66517755; called by muse, mutect2, varscan2
- OR9G1 | c.876G>A p.R292= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs558541089, COSV56453971; called by muse, mutect2, varscan2
- PARP16 | c.805C>T p.L269= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs780616392, COSV56036589; called by muse, mutect2, varscan2
- PCDH18 | c.2982G>A p.E994= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV61271958; called by muse, mutect2, varscan2
- PCDHB14 | c.324G>A p.V108= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs199548868; called by muse, mutect2, varscan2
- PDE4A | c.1842C>T p.F614= (on ENST00000380702 / NM_001111307.2; = p.F375= on NM_006202.3) | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV53362053; called by muse, mutect2, varscan2
- POM121L12 | c.423C>T p.I141= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs749775104, COSV68692276; called by mutect2, varscan2
- PRAMEF8 | c.126G>A p.E42= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- PRLR | c.606C>T p.Y202= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV51500442; called by muse, mutect2, varscan2
- PTGER2 | c.819C>T p.F273= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV55418583; called by muse, mutect2, varscan2
- PTPN23 | c.4110C>T p.F1370= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV55548269; called by muse, mutect2, varscan2
- RANBP6 | c.2496T>C p.V832= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as COSV52391524; called by muse, mutect2, varscan2
- RGL4 | c.279G>A p.R93= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV51945320; called by muse, mutect2, varscan2
- RPGRIP1 | c.1620G>A p.L540= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV52856976; called by muse, mutect2, varscan2
- SCRN2 | c.1096C>T p.L366= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1191050120, COSV51636102, COSV51637304; called by muse, mutect2
- SCRN3 | c.15C>T p.S5= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs1358309254, COSV99767157; called by muse, mutect2, varscan2
- SEC16A | c.5313C>T p.F1771= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV51540256; called by muse, mutect2, varscan2
- SELENOV | c.1017C>T p.I339= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs537964754, COSV59064742; called by muse, mutect2, varscan2
- SEMA4F | c.351G>A p.K117= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV60285194; called by muse, mutect2, varscan2
- SEPTIN4 | c.897G>A p.V299= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV57897266, COSV57899490; called by muse, mutect2, varscan2
- SGK1 | c.1104T>C p.I368= | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as COSV52814843; called by muse, mutect2, varscan2
- SLC6A14 | c.555C>T p.I185= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs140784139, COSV64146207; called by muse, mutect2, varscan2
- SLC7A6 | c.211C>T p.L71= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV54720767; called by muse, mutect2, varscan2
- SNTB1 | c.831C>T p.I277= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV67329128; called by muse, mutect2, varscan2
- SPTBN4 | c.6006G>A p.Q2002= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58958223; called by muse, mutect2, varscan2
- SRPX | c.132C>T p.V44= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs746793180, COSV59440120; called by muse, mutect2, varscan2
- STAT3 | c.243C>T p.H81= | Silent (SNP) | VAF 68/223 reads (30%) | catalogued as COSV99232988; called by muse, mutect2, varscan2
- TC2N | c.1170C>T p.F390= | Silent (SNP) | VAF 67/232 reads (29%) | catalogued as rs776984565, COSV61746360, COSV61747345; called by muse, mutect2, varscan2
- TECTA | c.3642C>T p.G1214= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV50800721; called by muse, mutect2, varscan2
- TENM4 | c.4296C>T p.I1432= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV53667948; called by muse, mutect2
- TEP1 | c.312C>T p.I104= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV52999744; called by muse, mutect2, varscan2
- THYN1 | c.252C>A p.P84= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV55542547; called by muse, mutect2, varscan2
- TM2D2 | c.288C>T p.S96= (on ENST00000456397 / NM_078473.3; = p.S53= on NM_031940.4) | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV101166185; called by muse, mutect2, varscan2
- TMC5 | c.18G>A p.R6= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV66867077; called by muse, mutect2, varscan2
- TMC7 | c.1398C>T p.I466= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV58582059; called by muse, varscan2
- TMEM132D | c.639G>A p.R213= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1174914505, COSV70604060; called by muse, mutect2, varscan2
- TNIP3 | c.861T>A p.A287= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV50253826; called by muse, mutect2, varscan2
- TRIOBP | c.1131C>T p.N377= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs767007563, COSV60384057; called by muse, mutect2, varscan2
- TTN | c.95460T>C p.L31820= (on ENST00000591111; = p.L24396= on NM_003319.4) | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV60332954; called by muse, mutect2, varscan2
- WNT2B | c.12C>T p.G4= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV56676893; called by muse, mutect2, varscan2
- YJEFN3 | c.144G>A p.R48= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV53065235; called by muse, mutect2, varscan2
- ZNF462 | c.5121C>T p.P1707= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV52950470; called by muse, mutect2, varscan2
- ZNF486 | c.183G>A p.L61= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV58722453; called by muse, mutect2, varscan2
- ZNF605 | c.168C>T p.L56= | Silent (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- ZZZ3 | c.246C>T p.S82= | Silent (SNP) | VAF 66/185 reads (36%) | catalogued as COSV66235427; called by muse, mutect2, varscan2
- DCHS2 | n.5047C>T | RNA (SNP) | VAF 18/45 reads (40%) | catalogued as COSV61774154; called by muse, mutect2, varscan2
- FBLN1 | c.1698-9559C>T | Intron (SNP) | VAF 13/45 reads (29%) | catalogued as COSV53053851; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.176C>T | RNA (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.10360+5165G>A | Intron (SNP) | VAF 18/48 reads (38%) | catalogued as rs1423179867, COSV100621582; called by muse, mutect2, varscan2
- UPK2 | c.*2G>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99875078; called by mutect2, varscan2
